Surgical pathology report (de-identified scan), TCGA case TCGA-76-4926, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Thomas Jefferson University, specimen TCGA-76-4926-01B (Primary Tumor).

[page 1 of 2]
Patient: [REDACTED]

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. Right frontal brain tumor: glioblastoma multiforme, grade IV of IV (WHO Scale) see microscopic description
2. Right frontal brain tumor: glioblastoma multiforme, grade IV of IV (WHO Scale), see microscopic description

[REDACTED]
Report Electronically Signed

This diagnostic report has been personally interpreted by the signatory of record.

[REDACTED]

Microscopic Description:

The tumor consists of a moderately pleomorphic and infiltrative proliferation of astrocytic cells. There are multiple mitoses and extensive necrosis, some of which displays a pseudopalisading pattern. There is no significant endothelial proliferation. The findings are diagnostic of a glioblastoma multiforme, grade IV of IV (WHO Scale).

Frozen Section Diagnosis:

1. Necrotic tissue with foci of atypical glial cells consistent with glioma, malignant. More tissue requested if clinically indicated.

Clinical History and Diagnosis:

Right frontal brain tumor

[page 2 of 2]
Source of Specimen:

- 1: Right frontal brain tumor
- 2: Right frontal brain tumor

Gross Description:

1. Right frontal brain tumor: Received in formalin are multiple fragments of red-tan soft tissue measuring 4.4 x 0.4 x 0.2 cm in aggregate. Touch preparation slides are created and the specimen is entirely submitted in one cassette for frozen section.
2. Right frontal brain tumor: Received in formalin are multiple fragments of red-tan soft tissue measuring 2.0 by 1.5 x 0.5 cm in aggregate. The specimen is entirely submitted in two cassettes.

Histology Laboratory
H&E

Source: NCI Genomic Data Commons file d9cb392a-8acd-4219-9df0-11e897414e27 (TCGA-76-4926.1DC2749E-BFE1-4F6F-BA92-C916F8AAEDD8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).